Somatic mutation profile of tumor specimen 0DSBYE from CCDI case PBCHPL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Aggressive fibromatosis; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 12.8 years (4,676 days).
Specimen 0DSBYE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 418fc433-8d63-4d2a-b725-78c2b95f45a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSBY5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef20e6e8-9e42-44eb-88de-c3d9a7114ffe

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Frame Shift Del 2, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.5815del p.D1939Tfs*31 | Frame Shift Del (DEL) | VAF 138/466 reads (30%) | catalogued as COSV57384864, COSV99970817; called by mutect2, varscan2
- DOCK6 | c.4441G>A p.A1481T | Missense Mutation (SNP) | VAF 83/399 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as rs140032702; called by muse, mutect2
- EFS | c.1469C>T p.T490I | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762424134; called by muse, mutect2, varscan2
- APC | c.3401_3428del p.D1134Vfs*22 | Frame Shift Del (DEL) | VAF 93/552 reads (17%) | called by mutect2, varscan2
- PRDM13 | c.260A>T p.D87V | Missense Mutation (SNP) | VAF 38/440 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RASL11A | c.513_516dup p.F173Pfs*4 | Frame Shift Ins (INS) | VAF 95/346 reads (27%) | called by mutect2, varscan2
- TSPAN5 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 81/698 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- VCPIP1 | c.2933T>C p.L978S | Missense Mutation (SNP) | VAF 92/524 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C12orf56 | c.705C>T p.S235= | Silent (SNP) | VAF 88/304 reads (29%) | catalogued as rs1451469100; called by mutect2, varscan2
- DGKA | c.942G>C p.A314= | Silent (SNP) | VAF 82/263 reads (31%) | catalogued as rs1239408705, COSV59387716; called by muse, mutect2, varscan2
- KIF7 | c.1347C>T p.G449= | Silent (SNP) | VAF 6/104 reads (6%) | catalogued as rs1362610541; called by muse, mutect2
- WNT6 | c.-53T>G | 5'UTR (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
